FM case AD14085 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/bc003422-9485-4b9f-a42d-66d997327f21

Male, 45.9 years: Medullary carcinoma, NOS (ICD-O-3 8510/3) of the thyroid gland; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
